Somatic mutation profile of tumor specimen TCGA-CN-6018-01A (aliquot TCGA-CN-6018-01A-11D-1683-08) from TCGA case TCGA-CN-6018, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 85.5 years (31,242 days).
Specimen TCGA-CN-6018-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 660e0496-1724-4bc5-a171-7e58a7cb75c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6018-10A (Blood Derived Normal), aliquot TCGA-CN-6018-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0d692f9-a4fb-414f-b79f-7047487bb117

The open-access MAF lists 114 somatic variants for this specimen: 82 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 30, Frame Shift Del 4, Nonsense Mutation 3, Splice Region 2, In Frame Ins 1, 5'Flank 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.5238G>C p.G1746= | Splice Region (SNP) | VAF 26/54 reads (48%) | catalogued as COSV101037407; called by muse, mutect2, varscan2
- ADH1B | c.306_307del p.R102Sfs*3 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs775840233; called by pindel, varscan2
- AHI1 | c.1568G>C p.R523T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99663353; called by muse, mutect2
- ALDH1A2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as rs779670359; called by muse, mutect2, varscan2
- ATP10B | c.3979C>G p.L1327V | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.073); catalogued as rs1396994309, COSV100515481, COSV59149597; called by muse, mutect2, varscan2
- BRD1 | c.2405G>A p.R802Q (on ENST00000216267 / NM_001349940.1; = p.R933Q on NM_001304808.3) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.493); catalogued as rs140147452, COSV99349329; called by muse, mutect2, varscan2
- BSX | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); catalogued as COSV58005629; called by muse, mutect2
- C3orf84 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs781681179, COSV100234279; called by muse, mutect2, varscan2
- CERT1 | c.587C>T p.S196F (on ENST00000405807 / NM_001130105.1; = p.S68F on NM_005713.3) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99783549; called by muse, mutect2
- CTCFL | c.1439A>G p.H480R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99713096; called by muse, mutect2, varscan2
- CYP11B2 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV100011264; called by muse, varscan2
- CYSLTR1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772170849, COSV100964748; called by muse, mutect2, varscan2
- DLG5 | c.5395G>A p.D1799N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV64946664; called by muse, mutect2, varscan2
- DOCK11 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99354377; called by muse, mutect2
- DOP1B | c.6004G>A p.E2002K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101215701; called by muse, mutect2, varscan2
- DPP10 | c.679G>C p.A227P | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV100069974; called by muse, mutect2, varscan2
- DSCAML1 | c.3391C>T p.R1131W (on ENST00000321322; = p.R1071W on NM_020693.4) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs563772293, COSV100354855; called by muse, mutect2, varscan2
- EXOC3L2 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as rs1026885638, COSV99374600; called by muse, mutect2, varscan2
- FAM118B | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV100796920; called by muse, mutect2, varscan2
- FAM178B | c.1914G>T p.E638D (on ENST00000490605 / NM_001122646.3; = p.E78D on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100014411; called by muse, mutect2, varscan2
- FAT1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 26/178 reads (15%) | catalogued as COSV101499519; called by muse, mutect2, varscan2
- FSIP2 | c.18049A>T p.I6017F | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100555845; called by muse, mutect2, varscan2
- GDI1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1557198952, COSV99341131; called by muse, mutect2
- GJA9 | c.1074T>G p.F358L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100668146; called by muse, mutect2, varscan2
- GK2 | c.668T>C p.F223S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100726013; called by muse, mutect2, varscan2
- GNAZ | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99321055; called by muse, mutect2, varscan2
- GPC5 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.437); catalogued as COSV100995113; called by muse, mutect2, varscan2
- HS6ST2 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); catalogued as COSV100897311, COSV63711013; called by muse, mutect2, varscan2
- IGHV3-49 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.03); catalogued as rs782186206; called by muse, mutect2, varscan2
- KCNK5 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.362); catalogued as rs938999027, COSV100851907; called by muse, varscan2
- LONRF2 | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs777776322, COSV101111016; called by muse, mutect2, varscan2
- LRFN5 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV99984919; called by muse, mutect2, varscan2
- LRRFIP1 | c.1195G>A p.D399N (on ENST00000392000 / NM_001137552.2; = p.D375N on NM_004735.4) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as COSV99791088; called by muse, mutect2
- LTBP3 | c.1763G>A p.G588E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100100065; called by muse, mutect2, varscan2
- MATN4 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | PolyPhen probably damaging (0.946); catalogued as rs757204270, COSV59213331; called by muse, mutect2, varscan2
- MDN1 | c.15067G>C p.E5023Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV101021638; called by muse, mutect2, varscan2
- MELTF | c.1544A>G p.N515S | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756445772, COSV99586448; called by muse, mutect2, varscan2
- METAP1 | c.1126G>C p.D376H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs776450607, COSV99595808; called by muse, mutect2
- MINAR1 | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100549098; called by muse, mutect2
- MYOF | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100826024; called by muse, mutect2
- NCL | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV100502433; called by muse, mutect2, varscan2
- NDUFS2 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100917518; called by muse, mutect2, varscan2
- NUP93 | c.2223C>A p.I741= | Splice Region (SNP) | VAF 17/146 reads (12%) | catalogued as COSV100360395; called by muse, mutect2, varscan2
- PABPC4 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100790908; called by muse, mutect2, varscan2
- PCSK2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99360293; called by muse, mutect2, varscan2
- PDE4A | c.1420G>A p.D474N (on ENST00000380702 / NM_001111307.2; = p.D235N on NM_006202.3) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53353843; called by muse, mutect2, varscan2
- PDGFRB | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as rs375343084, COSV55812133; called by muse, mutect2
- PDHA2 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV54777620, COSV54779251, COSV99757146; called by muse, mutect2, varscan2
- PGD | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99581600; called by muse, mutect2, varscan2
- PIM1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs773910971, COSV100998747, COSV65164775; called by muse, mutect2, varscan2
- POLDIP3 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99349263; called by muse, mutect2
- POLE | c.6409G>A p.E2137K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs879783561, COSV57674949; ClinVar: uncertain significance; called by muse, mutect2
- RALYL | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.189); catalogued as rs766059077, COSV101569346; called by muse, mutect2, varscan2
- RANBP17 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66645576; called by muse, mutect2
- RASGRP1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1330653682, COSV60363933; called by muse, mutect2
- SI | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV100016592; called by muse, mutect2, varscan2
- SLC38A10 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs373504148; called by muse, mutect2, varscan2
- SOWAHB | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100530764; called by muse, mutect2
- TAF7L | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 102/283 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs145455495, COSV61256962; called by muse, mutect2, varscan2
- TBXAS1 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99695744; called by muse, mutect2, varscan2
- TGM5 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370983556, CM1411737; called by muse, mutect2, varscan2
- TTYH3 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774889237, COSV99350023; called by muse, mutect2, varscan2
- UBE3B | c.3034G>T p.G1012C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100688971, COSV61075120; called by muse, mutect2, varscan2
- UGT2A3 | c.1319C>A p.A440D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99280118; called by muse, mutect2, varscan2
- UNC5D | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.979); catalogued as rs149536132, COSV54820228; called by muse, mutect2, varscan2
- VCAN | c.5465C>T p.T1822I | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV54105306; called by muse, mutect2, varscan2
- WSCD2 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV54579411; called by muse, mutect2
- ZAN | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.311); catalogued as rs761029874, COSV100770023; called by mutect2, varscan2
- ZBTB49 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV100552536; called by muse, mutect2, varscan2
- ZC3HC1 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772835691, COSV100315949; called by muse, mutect2, varscan2
- ZIM2 | c.794T>G p.L265R | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV55630675, COSV55637388; called by muse, mutect2, varscan2
- ZNF18 | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.04); catalogued as rs1390814387, COSV100503160; called by muse, mutect2, varscan2
- ZNF665 | c.478C>T p.Q160* (on ENST00000600412; = p.Q225* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | catalogued as COSV101128696; called by muse, mutect2
- ZNF670 | c.662G>C p.G221A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV100829318; called by muse, mutect2, varscan2
- ZNF831 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV64040627; called by muse, mutect2, varscan2
- ZSCAN22 | c.1341G>C p.Q447H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV61638835; called by muse, mutect2, varscan2
- CDC40 | c.148_149del p.L50Sfs*13 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by pindel, varscan2
- GPRIN3 | c.990_992dup p.S330dup | In Frame Ins (INS) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- HNRNPL | c.1508dup p.H504Afs*16 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.4751del p.Q1584Rfs*17 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- SAV1 | c.259del p.R87Efs*17 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- ABCG4 | c.1131C>G p.L377= | Silent (SNP) | VAF 45/397 reads (11%) | catalogued as COSV100266929; called by muse, mutect2, varscan2
- ACVRL1 | c.1233G>T p.R411= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- ARNT2 | c.999G>A p.V333= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs1480258391, COSV100309316; called by muse, mutect2
- BCL11A | c.1128C>T p.C376= (on ENST00000335712 / NM_001365609.1; = p.C410= on NM_018014.4) | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV59625494; called by muse, mutect2, varscan2
- CA11 | c.399G>C p.L133= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV99320771; called by muse, mutect2, varscan2
- CLCN2 | c.1044G>A p.V348= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99658838; called by muse, mutect2, varscan2
- DUSP11 | c.780C>G p.P260= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as rs1419311005; called by muse, mutect2
- ELFN2 | c.810C>T p.D270= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs202059228, COSV101297607; called by muse, mutect2, varscan2
- EPHX4 | c.102C>T p.I34= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100952748; called by muse, mutect2, varscan2
- FAT4 | c.1923G>A p.L641= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV101272544; called by muse, mutect2, varscan2
- GDPD4 | c.726C>T p.F242= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV100265501; called by muse, mutect2, varscan2
- GRM7 | c.306C>T p.G102= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs765037223, COSV63137069; called by muse, mutect2, varscan2
- HNF1B | c.987G>A p.L329= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- LRRC31 | c.1527G>C p.V509= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV99246943; called by muse, mutect2, varscan2
- MAGEA10 | c.285G>A p.S95= | Silent (SNP) | VAF 16/336 reads (5%) | catalogued as rs139926957, COSV99726845; called by muse, mutect2
- MROH1 | c.546C>T p.R182= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs374628763; called by muse, mutect2, varscan2
- MRPL9 | c.261G>A p.K87= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV100162627; called by muse, mutect2, varscan2
- NRXN3 | c.342C>T p.A114= (on ENST00000557594 / NM_001272020.2; = p.A746= on NM_004796.6) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs778188448, COSV99820749; called by muse, mutect2, varscan2
- PAK5 | c.357C>T p.H119= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as rs767346680, COSV62029632; called by muse, mutect2, varscan2
- SACS | c.11481G>A p.K3827= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV101207567; called by muse, mutect2, varscan2
- STRC | c.555C>T p.G185= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV101405445; called by mutect2, varscan2
- TENM1 | c.66T>A p.A22= | Silent (SNP) | VAF 34/303 reads (11%) | catalogued as COSV100950504; called by muse, mutect2, varscan2
- TYMP | c.375C>T p.V125= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV99329704; called by muse, mutect2
- UBE3B | c.3033G>T p.L1011= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100688969; called by muse, mutect2, varscan2
- WNK1 | c.1779A>G p.V593= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs772544134, COSV100268058; called by muse, mutect2, varscan2
- ZC3H12B | c.2196G>A p.P732= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs747943213, COSV59046222; called by muse, mutect2, varscan2
- ZNF154 | c.528C>G p.L176= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs771206222, COSV101377533, COSV70745029; called by muse, mutect2, varscan2
- ZNF195 | c.1395C>A p.P465= (on ENST00000399602 / NM_001130520.3; = p.P393= on NM_007152.5) | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99138083; called by muse, mutect2, varscan2
- ZNF2 | c.339C>T p.H113= (on ENST00000611147 / NM_001291605.2; = p.H100= on NM_021088.4) | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs549494037, COSV54638773; called by muse, mutect2, varscan2
- ZNF649 | c.699C>A p.P233= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895792 G>A | 5'Flank (SNP) | VAF 21/129 reads (16%) | catalogued as rs779108094, COSV60001008; called by muse, mutect2, varscan2
- ZNF99 | c.*693C>A | 3'UTR (SNP) | VAF 6/34 reads (18%) | catalogued as COSV101233906, COSV68055429; called by muse, varscan2
